Somatic mutation profile of tumor specimen 0DNYO0 from CCDI case PBCCFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,076 days).
Specimen 0DNYO0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b7acce4-e161-4f42-9c76-294215c72565.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNYNL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42caca43-59b6-4b0d-a57f-1ffbbb90319a

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 4, Nonsense Mutation 2, Intron 2, Silent 1, 3'Flank 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 95/557 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 80/290 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH17 | c.5640+5G>A | Splice Region (SNP) | VAF 28/200 reads (14%) | catalogued as rs140543216; called by muse, mutect2
- FN1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 48/666 reads (7%) | catalogued as COSV60548120; called by muse, mutect2
- MAP3K1 | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 99/479 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68123876; called by muse, mutect2, varscan2
- POU2F2 | c.561C>A p.C187* (on ENST00000526816 / NM_001207025.3; = p.C171* on NM_002698.5) | Nonsense Mutation (SNP) | VAF 37/243 reads (15%) | catalogued as COSV100657141; called by muse, mutect2, varscan2
- ROBO2 | c.1814A>T p.D605V | Missense Mutation (SNP) | VAF 120/632 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59921200; called by muse, mutect2, varscan2
- ATP9B | c.1677G>C p.E559D | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- EDA2R | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PTPRB | c.5090C>T p.A1697V | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- REV3L | c.5021C>T p.P1674L | Missense Mutation (SNP) | VAF 137/589 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPESP1 | c.291A>T p.E97D | Missense Mutation (SNP) | VAF 86/414 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- HCN1 | c.513A>C p.T171= | Silent (SNP) | VAF 56/742 reads (8%) | called by muse, mutect2
- ACBD4 | chr17:45143586 G>A | 3'Flank (SNP) | VAF 87/385 reads (23%) | catalogued as rs779255807; called by muse, mutect2, varscan2
- C9orf57 | c.*45G>A | 3'UTR (SNP) | VAF 12/134 reads (9%) | catalogued as rs138886794, COSV65462655; called by muse, mutect2
- CD209 | chr19:7747541 C>A | 5'Flank (SNP) | VAF 34/178 reads (19%) | called by muse, mutect2, varscan2
- EPS8L2 | c.*43C>G | 3'UTR (SNP) | VAF 9/79 reads (11%) | called by muse, varscan2
- MYO1D | c.*29G>A | 3'UTR (SNP) | VAF 34/153 reads (22%) | catalogued as rs371439625; called by muse, varscan2
- PNPLA8 | c.1207-41G>C | Intron (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- SYMPK | c.1598+88G>T | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- TEAD3 | c.*59G>T | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
